Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A5TT, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A5TT-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3
Oligodendroglioma
grade II 945113
CCCF
Site Supratentorial NOS
C71.0
path
① Brain, frontal lobe
C71.1
JW 4/12/13

Surgical Pathology Report

PatientName: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age: Location: Received:
Gender: M Acct: Reported:
Physician(s):
Phy Location:
Copy To:

Clinical History

-year-old man experienced new onset seizure, and on imaging study had a mostly non-enhancing lesion in the left frontal premotor area at the level of the middle frontal gyrus, without choline spike. However, seizure activity has increased and enhancement appears to have enlarged.

Operative Diagnoses

Left frontal brain tumor

Operation / Specimen

A: Brain pure tumor, biopsy

B: Brain pure tumor, biopsy

Pathologic Diagnosis

A, B. Brain, left frontal tumor, excisional biopsies:

1. Oligodendroglioma, anaplastic (WHO 3).
2. 1p, 19q LOH (codelation): Positive.
3. IDH1-R132H, immunohistochemistry: Negative.
4. Methylated MGMT promoter: Positive.
5. MIB-1 proliferation Index: 18%.

See Microscopy Description and Comment.

Comment

The sections contain portions of cerebrum that are infiltrated and extensively effaced by a glial neoplastic proliferation in which there are frequently mitoses. The neoplasm has a mixed cellularity. The MIB-1 proliferation index is 18%

in the more active areas. There is focal microvascular cellular proliferation. There is not tumor necrosis. The morphological features are those of a glioma with anaplastic features. The glioma has codelation of arms 1p

and 19q, a feature characteristic of oligodendrogliomas.

Electronically Signed Out

Consultant:

Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Surgical Pathology

Page 2 of 4

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

Informative loci are: D1S1592, D1S552, D19S219, D19S412

Results-Comments

Testing performed on DNA extracted from tumor paraffin block from a

(A1). DNA extracted

[page 2 of 3]
corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

MGMT Promoter methylation

Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1)

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

Surgical Pathology

Page 3 of 4

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

[page 3 of 3]
was developed and its performance characteristics determined by the
as required
by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug
Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These
results are
provided for informational purposes only, and should be interpreted only in the context of established
procedures
and/or diagnostic criteria.
Electronically Signed Out

Intra-Operative Consultation

A.

Brain tumor, biopsy: Glioma, probably astrocytic and high grade? (Microvascular proliferation), other..

Touch preparation smears performed at
Record.

and results reported to the Physician of

Senior

Staff Pathologist

Gross Description

A.

"Left frontal brain tumor," received fresh, two fragments, 0.8 cm in aggregate. Soft, pinkish-grey,
glistening. In total,

A1.

B

."Left frontal brain tumor,"

Received fresh, several fragments, 1.2 cm in aggregate. Pieces of brain and greyish sot tissue. In total,
B1.

Microscopic Description

IMMUNOHISTOCHEMISTRY: The CD163 demonstrates numerous microglial cells in between the
neoplastic cells.

The IDH1 stain is negative. With the MIB-1 there is a proliferation index of about 18% in the more active
areas. The

CD34 depicts focal neovascularization and focal microvascular cellular proliferation.

ICD-9(s): 191.1 191.1

Billing Fee Code(s):

Histo Data

Part A: Brain pure tumor, biopsy

Taken:

Received:

Stain/cnt Block Ordered Comment

CD163 Vector x 1 1

CD34-DA x 1 1

H&E x 1 1

IDH1-sld x 1 1

LOH-curfs x 1 1

Surgical Pathology

Page4 of 4

Source: NCI Genomic Data Commons file 5abafeb1-e502-4d34-83a5-b1f596a05a65 (TCGA-DU-A5TT.6E55B698-D0BA-4834-91EE-0210657A9791.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).